Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A9PD, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A9PD-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED] Accession #: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED] Service Date: [REDACTED]
DOB: [REDACTED] Sex: Male Received: [REDACTED]
Soc. Sec. #: [REDACTED] Location: [REDACTED] Client: [REDACTED]
Physician(s): [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- ICD O-3*
Carcinoma, urothelial NOS
Site Bladder, anterior wall
8/28/13
C67.3
8/30/14
- A. Left ureter, biopsy: No dysplasia or carcinoma.
B. Right ureter, biopsy: No dysplasia or carcinoma.
C. Urinary bladder and prostate, cystoprostatectomy:
- Urinary bladder:
1. High-grade urothelial carcinoma invasive into perivesicular adipose tissue, margins negative; see comment.
2. No tumor in two lymph nodes (0/2).
- Prostate: Nodular stromal hyperplasia and glandular atrophy with focal squamous metaplasia, no carcinoma.
D. Lymph nodes, right obturator, dissection: No tumor in three lymph nodes (0/3).
E. Lymph nodes, right internal iliac, dissection: No tumor in seven lymph nodes (0/7).
F. Lymph nodes, right external iliac, dissection: No tumor in two lymph nodes (0/2).
G. Lymph nodes, left pelvic, dissection: No tumor in eleven lymph nodes (0/11).
H. Left ureter, resection: No dysplasia or carcinoma.
I. Right ureter, resection: No dysplasia or carcinoma.

COMMENT:

Bladder Tumor Synoptic Comment

[page 2 of 4]
-
- **Tumor type:** Urothelial carcinoma.
- **Tumor grade:** High grade.
- **Tumor size:** 3.2 x 2.5 x 1.8 cm.
- **Extent of tumor in bladder:** Invasive through muscularis propria into perivesicular tissue (slide C6).
- **Lymphatic/vascular invasion:** Present. Slide C4. An immunohistochemical stain for CD34 was obtained and confirms the presence of tumor within small vascular spaces.
- **Epithelial abnormalities in bladder:** None.
- **Extension of tumor into adjacent organs:** None.
- **Margins:**
- **Urethral margin:** Negative (invasive tumor is 4.8 cm from margin).
- **Right ureter margin:** Negative.
- **Left ureter margin:** Negative.
- **Perivesical margin:** Negative (tumor is 0.7 cm from margin).
- **Lymph node status:** Negative.
- total number of nodes examined: 25.
- **Other pathologic findings in bladder:** Foreign body giant cell reaction consistent with prior transurethral resection of bladder tumor.
- **AJCC/UICC stage:** pT3aN0.

While focal urothelial cell atypia is present on multiple frozen sections, the final permanent sections fail to show definitive urothelial dysplasia or carcinoma in situ in these sections. Dr. [REDACTED] has reviewed the frozen sections and corresponding permanent slides.

Specimen(s) Received

A: Left ureter (FS)
B: Right ureter (FS)
C: Bladder and prostate (FS on urethra)
D: Lymph node, right obturator
E: Lymph node, right internal iliac
F: Lymph node, right external iliac
G: Lymph node, left pelvic
H: Left ureter
I: Right ureter

Intraoperative Diagnosis

FS1 (A) Left ureter, biopsy: Focal urothelial atypia. No invasive carcinoma. Dr. [REDACTED] concurs. [REDACTED]

FS2 (B) Right ureter, biopsy: No high-grade dysplasia or invasive carcinoma. Dr. [REDACTED] concurs. ([REDACTED]

FS3 (C) Urethral margin, biopsy: Focal urothelial atypia, no invasive carcinoma. (Dr. [REDACTED])

Clinical History

The patient is an [REDACTED]-year-old man with a history of high-grade urothelial carcinoma [REDACTED] involving the left lateral wall. He now undergoes a radical cystoprostatectomy with bilateral lymph node dissection.

Gross Description

The specimen is received in nine parts, each labeled with the patient's name and unit number. Parts A-C are received fresh. Parts D-I are received in formalin.

Part A, additionally labeled "left ureter," consists of one, soft, pink, ovoid, irregular unoriented tissue fragment (0.8 x 0.8 x 0.3 cm). The entire specimen is frozen for frozen section diagnosis 1, and

[page 3 of 4]
subsequently submitted in cassette A1.

Part B, additionally labeled "right ureter," consists of one, soft, pink, irregular, unoriented tissue fragment (1.7 x 0.4 x 0.3 cm). The entire intact specimen is frozen for frozen section diagnosis 2, and subsequently submitted in cassette B1.

Part C, additionally labeled "bladder and prostate," consists of a cystoprostatectomy specimen containing bladder (312 gm; 10 cm from right to left x 4 cm from anterior to posterior x 22.2 cm from superior to inferior, with attached ureters) and prostate (4.5 cm from apex to base x 5.2 cm in width x 4.8 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: There is one soft, tan-pink to red, friable, fungating mass (3.2 x 2.5 x 1.8 cm) located along the left anterior wall, abutting the left ureteral orifice. The mass grossly appears to extend into the deep muscularis propria and is located 0.5 cm from the anterior surgical margin, 1.3 cm from the posterior margin and 4.8 cm from the urethral margin. The remainder of the bladder mucosa is edematous and pink-red. Within the prostate there are multiple tan, rubbery nodules (largest 0.5 cm in greatest dimension) located centrally and one yellow-tan 0.4 cm cyst in the right mid-gland. the remaining prostate parenchyma is tan-pink.

The ureters (left ureter 8.2 cm in length x 0.3 cm in diameter, right ureter 7.3 cm in length x 0.2 cm in diameter) are soft tan-brown without masses or lesions. One fleshy, tan lymph node is identified in the perivesicular soft tissue measuring 0.4 cm in greatest dimension. The seminal vesicle/vas deferens bundles are soft, lobulated, red-tan without obvious lesion or mass.

ORIENTED BY: Anatomic landmarks, trigone.

INTRAOPERATIVE EVALUATION: Frozen section of urethral margin, en face, is submitted for frozen section diagnosis 3.

INKING:

- Anterior right surface: Green.
- Anterior left surface: Blue.
- Posterior surface: Black.

GROSS PHOTOGRAPHS: Yes.

CASSETTES: Representative sections are submitted as follows:

- C1: Urethral margin, frozen remnant.
- C2: Left ureter margin, en face.
- C3: Right ureter margin, en face.
- C4: Mass at left anterior wall, margin.
- C5: Mass at closest approach to prostate.
- C6: Mass at left ureteral orifice, trigone.
- C7: Left posterior wall, adjacent to mass.
- C8: Right bladder wall.
- C9: Bladder dome wall.
- C10: Prostate, left apical margin, perpendicular.
- C11: Prostate, right apical margin, perpendicular.
- C12: Prostate, left apex.
- C13: Prostate, left mid gland.
- C14: Prostate, left base.
- C15: Prostate, right apex.
- C16: Prostate, right mid gland.
- C17: Prostate, right base.
- C18: Candidate lymph nodes, whole.
- C19: Posterior bladder wall.
- C20-C24: Candidate lymph nodes, whole.
- C25: Distal Prostatic urethra.

Part D, labeled "right obturator nodes," consists of a single, soft, roughly ovoid piece of tan and pale yellow fatty tissue (4.2 x 2 x 1.2 cm). Two candidate lymph nodes are found (0.1 cm and 3 cm in

[page 4 of 4]
[REDACTED]

greatest dimension). The candidate lymph nodes are submitted in cassette D1. The remaining fatty tissue is returned to the container.

Part E, labeled "right internal iliac nodes," consists of two, soft irregular pieces of brown and pale yellow fatty tissue (5.2 x 3.6 x 1.5 cm in aggregate). Seven candidate lymph nodes are found (0.5 cm to 1.1 cm in greatest dimension). The candidate lymph nodes are submitted in cassette E1. The remaining fatty tissue is returned to the container.

Part F, labeled "right external iliac nodes," consists of two, soft, irregular pieces of brown and yellow fatty tissue (3.2 x 1.7 x 0.9 cm in aggregate). Two candidate lymph nodes are found (0.7 cm and 0.8 cm in greatest dimension). The candidate lymph nodes are submitted in cassette F1. The remaining fatty tissue is returned to the container.

Part G, labeled "left pelvic lymph nodes," consists of multiple, soft, irregular pieces of brown and yellow fatty tissue (5.5 x 3.5 x 1.7 cm in aggregate). Nine candidate lymph nodes are found (0.5 cm to 1.4 cm in greatest dimension). The candidate lymph nodes are submitted as follows:

Cassette G1: Seven nodes.

Cassette G2: Two nodes.

The remaining fatty tissue is returned to the container.

Part H, labeled "left ureter," consists of a single, firm, tubular piece of off-white tissue with attached brown fibrofatty tissue (1 cm length x 0.8 cm average diameter). The lumen is patent (0.2 cm diameter). One end has a metal clip; this end is inked blue, and the opposite end is inked black. The specimen is serially sectioned and no lesions are seen. The entire specimen is submitted as follows:

Cassette H1: Ends.

Cassette H2: Central sections.

Part I, labeled "final right ureter," consists of a single, firm, tubular piece of off-white tissue (2.8 cm length x 0.5 cm average diameter) with attached tan-yellow fibrofatty tissue. The lumen is pinpoint. One end has a metal clip; this end is inked blue, and the opposite end is inked black. The specimen is serially sectioned and no lesions are seen. The entire specimen is submitted as follows:

Cassette I1: Ends.

Cassettes I2-I3: Central sections.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED] Pathology Resident

[REDACTED] Pathologist
Electronically signed out on [REDACTED]

Source: NCI Genomic Data Commons file 7612cd43-e078-4d66-bda5-471ba644d4ab (TCGA-UY-A9PD.0698B674-4D6D-4FEF-8129-F66DF28A45F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).